TCGA case TCGA-YL-A8SO — Prostate Adenocarcinoma (TCGA-PRAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Prostate gland; Tissue source site: PROCURE Biobank. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5e3d0e50-afb4-4d2d-b4d9-5f320c573ba3

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Canada; Age at index: 64 years; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C61; Tissue or organ of origin: Prostate gland; Site of resection or biopsy: Prostate gland; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 64.6 years (23,584 days); Year of diagnosis: 2004; Method of diagnosis: Surgical Resection; AJCC clinical T: T1a; AJCC clinical M: M0; AJCC pathologic T: T3a; Primary gleason grade: Pattern 4; Secondary gleason grade: Pattern 5; Prior treatment: No; Residual disease: R1; Gleason score: 9.
   Pathology details: Tumor level prostate: Apex / Middle; Zone of origin prostate: Overlapping/multiple zones.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Bicalutamide; Days to treatment start: 1,387 days (3.8 years); Days to treatment end: 1,862 days (5.1 years); Treatment outcome: Complete Response.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Goserelin Acetate; Days to treatment start: 1,387 days (3.8 years); Treatment outcome: Treatment Ongoing.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (1 entry)
- Follow-up contacts recording only the day: day 3,247, day 3,479.

Molecular and laboratory tests
- Prostate-Specific Antigen (PSA): 0 ng/mL (day 3,247).

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-YL-A8SO-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 1,270 mg.
  Slide TCGA-YL-A8SO-01B-03-TSC: Section location: Top; Percent tumor cells: 30; Percent tumor nuclei: 60; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 60; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-YL-A8SO-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-YL-A8SO-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Prostate; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Histologic diagnosis: Prostate Adenocarcinoma Acinar Type; Zone of origin: Overlapping / Multiple Zones; Method initial path diagnosis: Transurethral resection (TURBT); Lymph nodes examined: No; Treatment outcome first course: Stable Disease; Biochemical recurrence indicator: No; New tumor event diagnosis indicator: No.
- Tumor levels: Tumor level: Apex; Tumor level: Middle.
- Stage record, Psa: PSA most recent results: 0.
- Stage record, Gleason grading: Gleason pattern primary: 4; Gleason pattern secondary: 5.
- Drug treatment 1: Pharmaceutical therapy drug name: Casodex.
- Drug treatment 2: Pharmaceutical therapy drug name: Zoladex.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Stable Disease; Treatment outcome at TCGA followup: Stable Disease; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 3,479 days; disease-specific survival: no event (censored), 3,479 days; progression-free interval: no event (censored), 3,479 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-YL-A8SO-01B-31D-A376-01): tumor purity 0.55, ploidy 2, whole-genome doublings 0.
